Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A6IG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A6IG-01A (Primary Tumor).

[page 1 of 6]
Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

Anat Path Reports

ICD-O-3
Carcinoma, squamous
cell NOS 807013
Site Buccal mucosa
CD6D
JW 6/12/13

* Final Report *

erified)

Patient Name:

MRN:

Location:

Client:

Submitting Phys:

Acc #:

DOB:

Gender:

M

Collected:

Received:

Reported:

Head and Neck

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. BUCCAL MUCOSA, RIGHT, WIDE LOCAL EXCISION, A1FS:

- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (2.4 X 2.0 X 0.8CM).
- PERINEURAL AND LYMPHOVASCULAR INVASION IDENTIFIED.
- ALL SURGICAL MARGINS FREE OF INVASIVE CARCINOMA (DEEP MARGIN AND PARTS B-E).
- SEE SYNOPTIC REPORT.

B. INFERIOR MARGIN, RIGHT, EXCISION, B1FS:

- BENIGN SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

C. POSTERIOR MARGIN, RIGHT, EXCISION, C1FS:

- MODERATE EPITHELIAL DYSPLASIA.
- NEGATIVE FOR INVASIVE CARCINOMA.

D. ANTERIOR MARGIN, RIGHT, EXCISION, D1FS:

- MILD EPITHELIAL DYSPLASIA, FOCAL.
- NEGATIVE FOR INVASIVE CARCINOMA.

E. SUPERIOR MARGIN, RIGHT, EXCISION, E1FS:

- BENIGN SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

F. BUCCAL MUCOSA, LEFT, WIDE LOCAL EXCISION, F1FS:

- HYPERPLASTIC SQUAMOUS MUCOSA WITH LICHENOID MUCOSITIS AND SCAR.
- SEE COMMENT.

G. ANTERIOR MARGIN, LEFT, EXCISION, G1FS:

- BENIGN SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

H. INFERIOR MARGIN, LEFT, EXCISION, H1FS:

- BENIGN SQUAMOUS MUCOSA.

[page 2 of 6]
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- I. POSTERIOR MARGIN, LEFT, EXCISION, I1FS:
- BENIGN SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- J. SUPERIOR MARGIN, LEFT, EXCISION, J1FS:
- BENIGN SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- K. LYMPH NODES, RIGHT LEVEL I, NECK DISSECTION:
- METASTATIC CARCINOMA IN ONE OF THREE LYMPH NODES (1/3).
- METASTATIC FOCUS MEASURES 1.5MM IN A 2.0CM LYMPH NODE.
- EXTRANODAL EXTENSION IDENTIFIED; TUMOR IS APPROXIMATELY 1.0MM BEYOND NODE CAPSULE.
- HISTOLOGICALLY UNREMARKABLE SALIVARY GLAND PARENCHYMA.
- L. LYMPH NODES, RIGHT LEVEL II, NECK DISSECTION:
- NINE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/9).
- M. LYMPH NODES, RIGHT LEVEL III, NECK DISSECTION:
- FIVE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/5).
- N. LYMPH NODES, RIGHT LEVEL IV, NECK DISSECTION:
- FIVE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/5).

Comment

Review of Part F frozen sections slides show hyperplastic squamous epithelium with scattered apoptotic cells and focally, dyskeratotic cells overlying a scar and a scattered chronic inflammatory infiltrate. Microinvasive squamous cell carcinoma is not identified on frozen or permanent sections. These findings were discussed with confirmed the laterality of all submitted specimens.

Electronically Signed by

Assisted by:

Synoptic Worksheet

A. Right buccal lesion, single = anterior; double - superior:

Clinical History:	No neoadjuvant therapy
Specimen:	Buccal mucosa (inner cheek)
Received:	Fresh
Procedure:	Resection
	Neck (lymph node) dissection: Right neck per operative note, Level I-IV
Specimen Integrity:	Intact
Specimen Size:	Greatest dimension: 4.5 cm
	Additional dimension: 4.5 cm
	Additional dimension: 1.5 cm
Specimen Laterality:	Right
Tumor Site:	Buccal mucosa (inner cheek)
Tumor Focality:	Single focus
Tumor Size:	Greatest dimension: 2.4 cm
	Additional dimension: 2.0 cm
	Additional dimension: 0.8 cm
Tumor Thickness (pT1 and pT2 tumors):	

[page 3 of 6]
At the center of the specimen, there is a friable ill-defined mucosal lesion measuring 2.4cm x 2.0cm in surface dimension and 0.8 cm in depth. The lesion is located 0.8 cm from the anterior surface, 0.8 cm from the posterior surface, 0.8 cm from the superior surface, 0.7 cm from the inferior surface and 0.5 cm from the deep surface. The specimen is inked as follows: anterior-blue, posterior-red, superior-orange, inferior-yellow, deep-black. A representative section of the lesion is submitted for tumor bank. The deep surface corresponding to the lesion is shaved and submitted for frozen section diagnosis. Additional sections are submitted as stated below. (Dictated by

CASSETTE SUMMARY:

A1FS: Deep margin corresponding to mucosal lesion, shaved
A2: Lesion, representative
A3: Lesion in relation to anterior surface, perpendicular section
A4: Lesion in relation to posterior surface, perpendicular section
A5: Lesion in relation to superior surface, perpendicular section
A6: Lesion in relation to inferior surface, perpendicular section

Specimen B is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as inferior margin. It consists of a portion of mucosa-lined soft tissue measuring 2.5 x 0.5 x 0.4 cm. The specimen is submitted entirely for frozen section diagnosis, then transferred to cassette B1FS. (Dictated by

Specimen C is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as posterior margin. It consists of a portion of mucosa-lined soft tissue measuring 2.3 x 0.5 x 0.3 cm. The specimen is submitted entirely for frozen section diagnosis, then transferred to cassette C1FS. (Dictated by

Specimen D is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as anterior margin. It consists of a portion of mucosa-lined soft tissue measuring 2.5 x 0.4 x 0.3 cm. The specimen is submitted entirely for frozen section diagnosis, then transferred to cassette D1FS. (Dictated by

Specimen E is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as superior margin. It consists of a portion of mucosa-lined soft tissue measuring 3.5 x 0.4 x 0.2 cm. The specimen is submitted entirely for frozen section diagnosis, then transferred to cassette E1FS. (Dictated by

Specimen F is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as left buccal lesion. It consists of a portion of mucosa-lined soft tissue measuring 1 x 0.8 x 0.4 cm. The external surface of the specimen is inked blue. The specimen is bisected and submitted entirely for frozen section diagnosis, then transferred to cassette F1FS. (Dictated by

Specimen G is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as "anterior buccal lesion, left, margin." It consists of a portion of mucosa-lined soft tissue measuring 2.2 x 0.2 x 0.2 cm. The specimen is submitted entirely for frozen section diagnosis, then transferred to cassette "G1FS." Dictated by

Specimen H is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as "inferior buccal lesion, left, margin." It consists of a portion of mucosa-lined soft tissue measuring 1.5 x 0.2 x 0.2 cm. The specimen is submitted entirely for frozen section diagnosis, then transferred to cassette "H1FS." Dictated by

Specimen I is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as "posterior buccal lesion, left, margin." It consists of a portion of mucosa-lined soft tissue measuring 0.6 x 0.4 x 0.3 cm. The specimen is submitted entirely for frozen section diagnosis, then transferred to cassette "I1FS." Dictated by

Specimen J is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as "superior buccal lesion left, margin." It consists of a portion of mucosa-lined soft tissue measuring 1.5 x 0.3 x 0.2 cm. The specimen is submitted entirely for frozen section diagnosis, then transferred to cassette "J1FS." Dictated by

[page 4 of 6]
Tumor Description:	Tumor thickness: 0.8 mm Measured from ulcerated surface Exophytic Endophytic Ulcerated
Macroscopic Extent of Tumor:	0.8cm from anterior, posterior and superior margins, 0.7cm from inferior margin, 0.5cm from deep margin
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G2: Moderately differentiated
Microscopic Tumor Extension:	Carcinoma invades skeletal muscle bundles
Margins:	Margins uninvolved by invasive carcinoma Distance from closest margin: 0.5 Unit of measurement: cm Margins involved by carcinoma in situ (includes moderate and severe dysplasia) Margin(s): Posterior margin
Treatment Effect:	Not identified
Lymph-Vascular Invasion:	Present
Perineural Invasion:	Present
Lymph Nodes, Extranodal Extension:	Present
Pathologic Staging (pTNM):	
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension Number of regional lymph nodes examined: 22 Number of regional lymph nodes involved: 1 Size (greatest dimension) of the largest positive lymph node: 2.0 cm
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified

Clinical History

Buccal mucosa cancer. Wide local excision of buccal mucosa, neck dissection, radial forearm free-flap, skin graft.

Specimen(s) Received

A: Right buccal lesion, single = anterior; double - superior
B: Inferior margin
C: Posterior margin
D: Anterior margin
E: Superior margin
F: Left buccal lesion
G: Anterior left buccal lesion margin
H: Inferior r left buccal lesion margin
I: Posterior left buccal lesion margin
J: Superior left buccal lesion margin
K: Level 1
L: Level 2
M: Level 3
N: Level 4

Gross Description

Specimen A is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as right buccal lesion, single anterior, double superior. It consists of a portion of mucosa-lined soft tissue measuring 4.5 cm from anterior-to-posterior, 4.5 cm from superior-to-inferior and 1.5 cm from superficial-to-deep. The specimen is oriented by the surgeon with a single stitch indicating anterior and a double stitch indicating superior.

[page 5 of 6]
Specimen K is received in formalin along with the patient's name, medical record number and labeled as "level 1." The specimen consists of a portion of fibroadipose tissue which measures 7.0 x 4.0 x 2.0 cm. A total of seven potential lymph nodes are identified in the fibroadipose tissue fragments, the largest one measuring 2.0 cm in diameter. No mass lesion is present. Representative sections are submitted as follows. (Dictated by

Specimen L is received in formalin along with the patient's name, medical record number and labeled as "level 2." The specimen consists of a fragment of fibroadipose tissue which measures 3.5 x 3.0 x 2.0 cm. A total of eleven potential candidate lymph nodes are identified in the tissue fragment, the largest one measuring 1.8 cm in diameter. Representative sections are submitted as follows. (Dictated by

Specimen M is received in formalin along with the patient's name, medical record number and labeled as "level 3." The specimen consists of a fragment of soft tissue measuring 3.0 x 1.8 x 1.4 cm. A total of seven potential lymph nodes are identified, the largest one measuring 0.9 cm in diameter. Representative sections are submitted as follows. (Dictated by

Specimen N is received in formalin along with the patient's name, medical record number and labeled as "level 4." The specimen consists of a portion of soft tissue measuring 4.0 x 3.5 x 3.0 cm. A total of six potential lymph nodes are identified, the largest one measuring 1.0 cm in diameter. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

K1:	Largest potential lymph node, bisected
K2:	Three potential lymph nodes
K3:	Three potential lymph nodes
L1:	Three potential lymph nodes
L2:	Three potential lymph nodes
L3:	One potential lymph node, bisected
L4:	One potential lymph node, bisected
L5:	One potential lymph node, bisected
L6:	One potential lymph node, bisected
L7:	One potential lymph node, bisected
M1:	Three potential lymph nodes
M2:	Three potential lymph nodes
M3:	One lymph node, bisected
N1:	Two potential lymph nodes
N2:	Three potential lymph nodes
N3:	One potential lymph node, bisected

Intraoperative Consult Diagnosis

A1FS: RIGHT BUCCAL LESION, (FROZEN SECTION): DEEP MARGIN IS BENIGN
B1FS: INFERIOR MARGIN, (FROZEN SECTION): BENIGN.
C1FS: POSTERIOR MARGIN, (FROZEN SECTION): BENIGN; POSSIBLE DYSPLASIA (MILD TO MODERATE)
D1FS: ANTERIOR MARGIN, (FROZEN SECTION): BENIGN; POSSIBLE DYSPLASIA (MILD TO MODERATE)
E1FS: SUPERIOR MARGIN, (FROZEN SECTION): BENIGN.
F1FS: LEFT BUCCAL LESION, (FROZEN SECTION): WELL-DIFFERENTIATED SQUAMOUS MUCOSA,
POSSIBLE

MICROINVASIVE CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

G1FS: LEFT ANTERIOR BUCCAL MARGIN (FROZEN SECTION): BENIGN.
H1FS: LEFT ANTERIOR BUCCAL MARGIN (FROZEN SECTION): BENIGN.
I1FS: LEFT POSTERIOR BUCCAL MARGIN (FROZEN SECTION): BENIGN.
J1FS: LEFT SUPERIOR BUCCAL MARGIN (FROZEN SECTION): BENIGN.

Frozen section results were communicated to the surgical team and were repeated back by

[page 6 of 6]
Pathologist:

Microscopic Description

Microscopic examination performed.

Source: NCI Genomic Data Commons file 455daaf0-bca3-4292-8906-8463e84b27f4 (TCGA-QK-A6IG.8E6661F2-D8EF-4B13-BD73-30A4F1DFEE1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).